Somatic mutation profile of tumor specimen TCGA-DU-A6S8-01A (aliquot TCGA-DU-A6S8-01A-12D-A32B-08) from TCGA case TCGA-DU-A6S8, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 74.2 years (27,084 days).
Specimen TCGA-DU-A6S8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 992235cd-ce12-447f-9eaf-0fca7ed7de74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A6S8-10A (Blood Derived Normal), aliquot TCGA-DU-A6S8-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00b45cd7-3075-4c04-9dcc-5fbe1ea97506

The open-access MAF lists 51 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 8, Frame Shift Del 4, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC11 | c.2885T>C p.I962T | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV100750533; called by muse, mutect2, varscan2
- ACTRT1 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100947506; called by muse, mutect2, varscan2
- ACTRT2 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV101007484; called by muse, mutect2
- ADRA2A | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350155054, COSV99701467; called by muse, mutect2, varscan2
- ANO1 | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.153); catalogued as rs764791417, COSV100303690; called by muse, varscan2
- ASPM | c.7666G>A p.A2556T | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99659540; called by muse, mutect2
- CEP85L | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs549584138, COSV100820975; called by muse, mutect2, varscan2
- CIAO3 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs768013074, COSV99284557; called by muse, mutect2, varscan2
- CIC | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50666818; called by muse, mutect2, varscan2
- CKAP5 | c.4222C>T p.L1408F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100370391; called by muse, mutect2, varscan2
- CLC | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376785804; called by muse, mutect2, varscan2
- CXorf66 | c.713A>C p.K238T | Missense Mutation (SNP) | VAF 141/314 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs761035590, COSV100983825; called by muse, mutect2, varscan2
- DSG1 | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99935578; called by muse, mutect2, varscan2
- FAM47A | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.835); catalogued as rs772009197, COSV100649728, COSV60499144; called by muse, mutect2, varscan2
- H2BC4 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.908); catalogued as rs754086710, COSV58415016, COSV58416157; called by muse, mutect2
- IFIT5 | c.1291A>G p.N431D | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100877915; called by muse, mutect2, varscan2
- IGF1 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61034767; called by muse, mutect2, varscan2
- IRAK1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782139311, COSV57653600; called by muse, mutect2, varscan2
- KLHL26 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.914); catalogued as COSV99962991; called by muse, mutect2, varscan2
- LANCL1 | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99286132; called by muse, mutect2
- NLRP13 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV61623896; called by muse, mutect2, varscan2
- NPAP1 | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100274788; called by muse, mutect2, varscan2
- NR0B1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV100973443; called by muse, mutect2, varscan2
- NUFIP2 | c.938A>G p.K313R | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs767005687, COSV99837219; called by muse, mutect2
- PKDREJ | c.1540G>A p.G514R | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as COSV53549469; called by muse, mutect2
- PKP3 | c.1181A>G p.D394G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV100520696; called by muse, mutect2, varscan2
- PLD1 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs1484817822, COSV60574497; called by muse, mutect2, varscan2
- RTN4RL1 | c.901T>C p.F301L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.039); catalogued as COSV100486422; called by mutect2, varscan2
- SLC35C2 | c.1052G>C p.G351A | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99709040; called by muse, mutect2, varscan2
- ST8SIA6 | c.1178G>A p.S393N | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV101112053; called by muse, mutect2, varscan2
- SUGCT | c.1068G>C p.K356N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV100000002; called by muse, varscan2
- TAS2R16 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99972159; called by muse, mutect2, varscan2
- TBR1 | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV101271407; called by muse, mutect2, varscan2
- TNKS2 | c.1145T>C p.I382T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.314); catalogued as COSV100860996; called by muse, mutect2
- TRIM2 | c.781G>A p.A261T (on ENST00000437508; = p.A288T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100107562; called by muse, mutect2, varscan2
- ZNF714 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV52509360; called by muse, mutect2, varscan2
- ERCC3 | c.1814del p.I605Tfs*6 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | called by mutect2, pindel, varscan2
- GTF3C1 | c.3077_3078del p.Y1026Cfs*14 | Frame Shift Del (DEL) | VAF 27/87 reads (31%) | called by mutect2, pindel, varscan2
- NDUFA7 | c.207_209del p.I69del | In Frame Del (DEL) | VAF 26/84 reads (31%) | called by pindel, varscan2
- SOWAHC | c.1189del p.L397Wfs*36 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- TAF1L | c.2049del p.F683Lfs*27 | Frame Shift Del (DEL) | VAF 55/100 reads (55%) | called by mutect2, pindel, varscan2
- A1CF | c.1315T>C p.L439= (on ENST00000373993 / NM_138932.2; = p.L431= on NM_014576.4) | Silent (SNP) | VAF 21/157 reads (13%) | catalogued as COSV99255275; called by muse, mutect2, varscan2
- ACSBG1 | c.1038C>T p.A346= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV99357017; called by muse, mutect2, varscan2
- CHD8 | c.1077A>G p.S359= (on ENST00000646647 / NM_001170629.2; = p.S80= on NM_020920.4) | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV101303041; called by muse, mutect2, varscan2
- KIAA0319 | c.2655G>A p.V885= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100985200; called by muse, mutect2, varscan2
- MYOM2 | c.1770G>A p.R590= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV50708832; called by muse, mutect2
- PDE3A | c.1710T>C p.S570= | Silent (SNP) | VAF 45/209 reads (22%) | catalogued as rs1403260784, COSV100761673; called by muse, mutect2, varscan2
- SLC17A9 | c.543C>T p.Y181= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs200256067, COSV64848277; called by muse, mutect2, varscan2
- ZNF99 | c.966T>C p.F322= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as COSV101233702; called by muse, mutect2, varscan2
- DNM2 | c.1336-1087G>A | Intron (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100116713; called by muse, mutect2
